Surgical pathology report (de-identified scan), TCGA case TCGA-XY-A8S2, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Spectrum Health, specimen TCGA-XY-A8S2-01A (Primary Tumor).

[page 1 of 4]
Research Gross Description

year-old male with left testicular mass

Research Dx

Left testicle, radical orchiectomy:

Mixed germ cell tumor. See case summary.

~~C&E~~ ICD-O-3
Carcinoma, embryonal NOS 9070/3
path
Tumor, mixed germ cell 9085/3
Site: Testis NOS C62.9
JW 1/17/14

CASE SUMMARY FOR TESTIS (RADICAL ORCHIECTOMY):

Serum tumor markers: Beta subunit of human chorionic gonadotropin (beta-hCG) elevation

Tumor focality: Unifocal

Tumor size:

Greatest dimension: 4 cm

Additional measurements: 3.8 x 3.1 cm

Macroscopic extent of tumor: Confined to the testis

Histologic type: Mixed germ cell tumor (embryonal carcinoma-95%, teratoma-2%, yolk sac tumor-2%, choriocarcinoma-1%)

Margins:

Spermatic cord margin: Uninvolved by tumor

Other margins: Not applicable

Microscopic tumor extension: None

Lymph-Vascular invasion: Present, focal

Pathologic staging (pTNM):

Primary tumor: pT2: Tumor limited to the testis and epididymis with vascular/lymphatic invasion

Regional lymph nodes: pNX: Cannot be assessed (not sampled)

Distant metastasis: Not applicable

Serum tumor markers (S): SX: LDH unknown, therefore cannot be evaluated

Additional pathologic findings: Focal intratubular germ cell neoplasia and intratubular embryonal carcinoma; testicular atrophy

AJCC Staging (7th edition) pT2 pNX pM: Not applicable

Research QC

Tumor T1:

95% tumor nuclei (all embryonal)

5% necrosis

0% normal

Tumor T2:

85% tumor nuclei (embryonal)

10% necrosis

5% normal (stroma)

Tumor T3:

95% tumor nuclei (all embryonal)

5% necrosis

0% normal

Tumor T4:

85% tumor nuclei (embryonal)

10% necrosis

5% normal (stroma)

Per TSS - 2 pieces sent. Both are
100% embryonal - per diagnostic
discrepancy form. SCR

[page 2 of 4]
Normal N1, 2, 3, and 4:
100% testis

Research Specimen

—

Specimen Process Time

Plasma/serum/buffy coat
Cold ischemia start time:
Plasma frozen
Serum frozen
Buffy coat frozen

Tissue:
Cold ischemia start time:
Formalin fixation start time:
Total cold ischemia time
Formalin fixation stop time
Total formalin fixation time:

Specimen Weight

T1-43 mg, T2-44 mg, T3-58 mg, T4-74 mg
N1-62 mg, N2-63 mg, N3-85 mg, N4-76 mg

Specimen Size

Plasma x 4
Serum x 3
Buffy coat x 1

Cryovials x 8
Normal x 4
Tumor x 4
Metastatic x 0

FFPE x 8
Normal x 4
Tumor x 4
Metastatic x 0

Study

Patient Consent

Yes

[page 3 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____

TSS Identifier: _____

TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____

Completed Date: _____

T2

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	mixed (95% embryonal, 2% teratoma, 2% yolk sac, 1% choriochoriocarcinoma)	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% embryonal (for both T2 and T3)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The portion of the tumor sampled for our biorepository was 100% embryonal. The overall tumor evaluated by the surgical pathologist contained additional tumor tissue composed of additional subtypes listed in section one of this form.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director _____

Date _____

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature _____

Date _____

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS):

TSS Identifier:

TSS Unique Patient Identifier:

Completed By (Interviewer Name on OpenClinica):

Completed Date:

73

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Mixed (95% embryonal, 2% teratoma, 2% yolk sac, 1% choriochoriocarcinoma)	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% embryonal (for both T2 and T3)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The portion of the tumor sampled for our biorepository was 100% embryonal. The overall tumor evaluated by the surgical pathologist contained additional tumor tissue composed of additional subtypes listed in section one of this form.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file ea443b29-9dbe-43b2-a707-454ba1b13e1e (TCGA-XY-A8S2.72DEE5F2-2821-4A4C-A36B-FFE65CED3753.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).